TCGA case TCGA-N8-A4PO — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Corpus uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2aad74b4-8d66-4563-8958-88d83f86556d

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (3)
1. Carcinosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8980/3; ICD-10 code: C54.0; Tissue or organ of origin: Isthmus uteri; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 66.0 years (24,124 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage II; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 781 days (2.1 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 0.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 33.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 101 days; Days to treatment end: 144 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Carcinosarcoma, NOS), site: Bone, NOS. Age at diagnosis: 66.5 years (24,282 days); Days to diagnosis: 158 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Recurrence of diagnosis 1 (Carcinosarcoma, NOS), site: Vagina, NOS. Age at diagnosis: 67.0 years (24,485 days); Days to diagnosis: 361 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 158 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 158 days.
- Day 361 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Vagina, NOS; Days to recurrence: 361 days.
- Days to follow up: 438 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 781 days (2.1 years); Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 119 kg; Height: 138 cm; BMI: 62.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N8-A4PO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 890 mg.
  Slide TCGA-N8-A4PO-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 20.
- Sample TCGA-N8-A4PO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N8-A4PO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Submitted tumor site: Uterus; Anatomic organ subdivision: Lower uterine segment/Isthmus uteri; Histologic diagnosis: Uterine Carcinosarcoma/ MMMT: Heterologous Type; Surgical approach at diagnosis: Minimally Invasive; Method initial path diagnosis: Office Endometrial Biopsy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 781 days; disease-specific survival: no event (censored), 781 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 158 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N8-A4PO-01A-11D-A28Q-01): tumor purity 0.93, ploidy 2.79, whole-genome doublings 1.
